FM case AD3944 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/dd4cbca0-4a07-42fc-abc2-e72dae044a65

Female, 84.3 years: Serous carcinoma, NOS (ICD-O-3 8441/3) of the ovary; metastasis biopsied or resected from the peritoneum. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
